Somatic mutation profile of tumor specimen TCGA-BG-A220-01A (aliquot TCGA-BG-A220-01A-11D-A159-09) from TCGA case TCGA-BG-A220, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.4 years (25,346 days).
Specimen TCGA-BG-A220-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 367f2e26-07d4-4ed3-9f22-b03df587d33a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A220-10A (Blood Derived Normal), aliquot TCGA-BG-A220-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc778591-b59b-4c60-b413-e326b84bc997

The open-access MAF lists 921 somatic variants for this specimen: 712 protein-altering or splice-affecting, 186 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 438, Frame Shift Del 187, Silent 186, Nonsense Mutation 29, Frame Shift Ins 28, Splice Site 11, Intron 11, Splice Region 10, In Frame Del 8, RNA 6, 3'UTR 3, 5'Flank 3.

Variants (750 of 921; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASPA | c.244dup p.M82Nfs*8 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs756198538; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MOCS2 | c.65del p.P22Hfs*2 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PXDN | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs587777572, CM117086, COSV53229306, COSV99414147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918732, CM971477, COSV99253095; ClinVar: likely pathogenic; called by mutect2, varscan2
- AADAC | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99233371; called by muse, mutect2, varscan2
- ABCA13 | c.5522G>A p.C1841Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101330032, COSV101330109; called by mutect2, varscan2
- ABCA13 | c.12320G>A p.S4107N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.913); catalogued as rs1316763432; called by muse, mutect2
- ABCB5 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs1562534062, COSV99328896; called by muse, mutect2, varscan2
- ABCB9 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99757796; called by muse, mutect2, varscan2
- ABCC1 | c.3863C>A p.P1288H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100579920; called by muse, mutect2, varscan2
- ABCF3 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs142912170; called by muse, varscan2
- ABL1 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1423362935, COSV100584282, COSV59330231; called by muse, mutect2, varscan2
- ABR | c.2296G>A p.D766N (on ENST00000302538 / NM_021962.5; = p.D729N on NM_001092.5) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV99348269; called by muse, mutect2, varscan2
- ABRAXAS1 | c.706A>G p.S236G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777651096, COSV99788544; called by muse, mutect2, varscan2
- ACOX3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs765806929, COSV100711957; called by muse, mutect2, varscan2
- ACTB | c.82del p.R28Gfs*16 | Frame Shift Del (DEL) | VAF 18/26 reads (69%) | catalogued as rs1260854008, COSV100079927, COSV59322102; called by mutect2, pindel, varscan2
- ACTN4 | c.2619del p.D874Tfs*44 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- ADAD1 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635941; called by muse, mutect2, varscan2
- ADAMTS2 | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.04); catalogued as rs758419331, COSV52363448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRV1 | c.4985G>A p.R1662H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs193222107, COSV67993512; called by muse, mutect2, varscan2
- ADNP | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs773922977, COSV100823790; called by muse, mutect2, varscan2
- ADRA2B | c.636del p.P213Lfs*140 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs756613487; called by pindel, varscan2
- AHCYL1 | c.963+2T>C p.X321_splice | Splice Site (SNP) | VAF 72/161 reads (45%) | catalogued as COSV100779619; called by muse, mutect2, varscan2
- AHNAK | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV57207876, COSV99948362; called by muse, mutect2, varscan2
- AHNAK2 | c.10203G>A p.M3401I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as COSV100318211, COSV60932802; called by muse, mutect2, varscan2
- ALDH1A2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs563668428, COSV51081097; called by muse, mutect2, varscan2
- ALPP | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461590076, COSV67396271; called by mutect2, varscan2
- ALX1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs150997122, COSV57492012; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 27/56 reads (48%) | catalogued as rs34047276; called by mutect2, varscan2
- ANKRD6 | c.1934C>T p.P645L (on ENST00000339746 / NM_001242809.2; = p.P640L on NM_014942.4) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1374040266, COSV60231153; called by muse, mutect2, varscan2
- ANO2 | c.1001C>T p.A334V (on ENST00000356134 / NM_001278597.3; = p.A338V on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469255109, COSV100501545; called by muse, mutect2, varscan2
- APOB | c.9311C>T p.A3104V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as COSV99266558; called by muse, mutect2, varscan2
- AR | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.281); catalogued as COSV101018747; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGEF2 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100904032; called by muse, mutect2, varscan2
- ARHGAP32 | c.3943G>A p.A1315T (on ENST00000310343 / NM_001378025.1; = p.A966T on NM_014715.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100088369; called by muse, mutect2, varscan2
- ARHGDIA | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV99482597; called by muse, mutect2, varscan2
- ARHGEF17 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs750004622, COSV99736127; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID4A | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100794449; called by muse, mutect2, varscan2
- ARNT2 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1391966698, COSV100308957; called by muse, mutect2, varscan2
- ARPP21 | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99492510; called by muse, mutect2, varscan2
- ARRDC4 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV51420466, COSV99164410; called by muse, mutect2, varscan2
- ASB13 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754407925, COSV100731401, COSV63091662; called by muse, mutect2, varscan2
- ASTN2 | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as COSV57804356; called by muse, mutect2, varscan2
- ASTN2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1387133062, COSV57767504; called by muse, mutect2, varscan2
- ATM | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1064797160, COSV53736315, COSV99590446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.3127C>T p.Q1043* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99980795; called by muse, mutect2, varscan2
- ATOH1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV100024544; called by muse, mutect2, varscan2
- ATP11A | c.3224C>T p.A1075V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs769836997, COSV99369250; called by muse, mutect2, varscan2
- AXDND1 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as rs754952987, COSV62642121; called by muse, mutect2, varscan2
- AXIN2 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as COSV100196707; called by muse, mutect2, varscan2
- B4GALNT1 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs149358222; called by muse, mutect2, varscan2
- BAG3 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as COSV100958261; called by muse, mutect2, varscan2
- BAHD1 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV60378771; called by muse, mutect2, varscan2
- BBS2 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs779292661, COSV99802596; called by muse, mutect2, varscan2
- BCAS4 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs202162521, COSV99372635, COSV99372714; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND3 | c.1922A>C p.E641A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100944637; called by mutect2, varscan2
- BID | c.460G>A p.G154S (on ENST00000317361 / NM_197966.2; = p.G108S on NM_001196.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs143198074; called by muse, mutect2, varscan2
- BMX | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564551; called by muse, mutect2, varscan2
- BNC1 | c.903del p.D302Ifs*4 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as COSV61756439; called by mutect2, pindel, varscan2
- BPIFA1 | c.666C>T p.N222= | Splice Region (SNP) | VAF 21/29 reads (72%) | catalogued as rs773494093, COSV62823863; called by muse, mutect2, varscan2
- BRAT1 | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100385159, COSV58093986; called by muse, mutect2, varscan2
- BSN | c.7513del p.T2506Hfs*63 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs754418611; called by mutect2, pindel, varscan2
- BTBD9 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100021217; called by muse, mutect2, varscan2
- C5AR2 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs759326628, COSV57257346; called by muse, mutect2, varscan2
- CACNA1B | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99498446; called by muse, mutect2, varscan2
- CACNA1F | c.4718C>T p.P1573L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100545084; called by muse, mutect2, varscan2
- CACNB2 | c.1858G>A p.E620K (on ENST00000324631 / NM_201596.3; = p.E565K on NM_000724.4) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as rs761643494, COSV56638507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as rs766121837, COSV99871710; called by muse, mutect2, varscan2
- CALCR | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1466204522, COSV100810498; called by muse, mutect2
- CALHM1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs756899682, COSV100324347; called by muse, mutect2, varscan2
- CALML3 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.715); catalogued as rs752809700, COSV100178855; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs745547658; called by mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARMIL2 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1230829943, COSV100576146; called by muse, mutect2, varscan2
- CATSPER1 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200131049, COSV100376091; called by muse, varscan2
- CATSPER3 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV99254224; called by muse, mutect2, varscan2
- CC2D1B | c.2478del p.K827Sfs*4 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs760045420; called by mutect2, pindel, varscan2
- CC2D2A | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs768618373, COSV101052822; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 76/90 reads (84%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC22 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs370575402, COSV100873198; called by muse, mutect2, varscan2
- CCDC9B | c.609del p.T204Rfs*44 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs772754432; called by mutect2, pindel, varscan2
- CCKBR | c.1316C>T p.T439I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100583014; called by muse, mutect2, varscan2
- CCNL2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100785005; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs761073142; called by mutect2, varscan2
- CCSER1 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100393910; called by muse, mutect2
- CCT6A | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs767086827, COSV99303587; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 14/22 reads (64%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs1230791486, COSV52278837, COSV99297977; called by muse, mutect2, varscan2
- CDH23 | c.8384G>A p.R2795Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs776710271, COSV56474353; called by muse, mutect2, varscan2
- CDRT4 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as COSV100381583; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CEACAM5 | c.1985C>G p.T662S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV99704031; called by muse, mutect2, varscan2
- CELSR1 | c.6602C>T p.A2201V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.294); catalogued as rs931511697, COSV99418993; called by muse, mutect2, varscan2
- CELSR2 | c.6152G>A p.R2051H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs781660638, COSV99604318; called by muse, mutect2, varscan2
- CELSR3 | c.5456G>A p.R1819Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1300631522, COSV51127622; called by muse, mutect2, varscan2
- CEP112 | c.2512C>T p.Q838* (on ENST00000392769 / NM_001353127.1; = p.Q94* on NM_001037325.3) | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100439311; called by muse, mutect2, varscan2
- CEP152 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV100358961; called by mutect2, varscan2
- CEP170 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs2993726; called by muse, mutect2
- CEP250 | c.852-2A>C p.X284_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100699046; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs747064410; called by mutect2, varscan2
- CEP89 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99993714; called by muse, mutect2, varscan2
- CES3 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV100309984; called by muse, mutect2, varscan2
- CFAP44 | c.2677C>A p.L893I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99869981; called by muse, mutect2, varscan2
- CHD3 | c.4789G>C p.A1597P | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100391374; called by muse, mutect2, varscan2
- CHD7 | c.4105G>T p.G1369* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101418329; called by muse, mutect2
- CHEK1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753180922, COSV99629778; called by muse, mutect2, varscan2
- CHL1 | c.1138G>A p.V380I (on ENST00000397491 / NM_001253387.1; = p.V396I on NM_006614.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.139); catalogued as COSV99851634; called by muse, mutect2, varscan2
- CIB1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs145803459; called by muse, mutect2, varscan2
- CLCA4 | c.218dup p.K74Qfs*9 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs745822656; called by mutect2, varscan2
- CLDN1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772875922, COSV99790666; called by muse, mutect2, varscan2
- CLDN15 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.381); catalogued as COSV99778970; called by muse, mutect2, varscan2
- CLEC14A | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100643625; called by muse, mutect2, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs760557093; called by mutect2, varscan2
- CLIP1 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100212023; called by muse, mutect2, varscan2
- CLNS1A | c.363G>A p.A121= | Splice Region (SNP) | VAF 18/37 reads (49%) | catalogued as rs139072243; called by muse, mutect2, varscan2
- CLOCK | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV100011880; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPX | c.1492G>T p.G498* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100269558; called by muse, mutect2, varscan2
- CLUH | c.1324dup p.D442Gfs*99 (on ENST00000435359; = p.D480Gfs*99 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs752224729; called by mutect2, varscan2
- CMSS1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs202161581, COSV101375602; called by muse, mutect2, varscan2
- CNGA4 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV101171829; called by muse, mutect2, varscan2
- CNGB1 | c.3096C>A p.S1032R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99204225; called by mutect2, varscan2
- CNKSR2 | c.3013A>G p.T1005A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101069956; called by muse, mutect2, varscan2
- CNTN3 | c.2413G>C p.A805P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.316); catalogued as COSV99725219; called by muse, mutect2
- CNTNAP4 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100272250; called by muse, mutect2, varscan2
- COBL | c.2971C>T p.Q991* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99473258; called by muse, mutect2
- COL11A1 | c.1350+1G>C p.X450_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100617330, COSV62196797; called by muse, mutect2, varscan2
- COL5A2 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880570; called by muse, mutect2, varscan2
- CORO7 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs775952526, COSV99227866; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.3111G>T p.Q1037H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99267667; called by muse, mutect2, varscan2
- CPAMD8 | c.2899G>A p.G967R (on ENST00000651564; = p.G920R on NM_015692.5) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs771137068, COSV71595924; called by muse, mutect2, varscan2
- CPNE1 | c.1387G>A p.A463T (on ENST00000352393; = p.A468T on NM_003915.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs778542371, COSV100467749; called by muse, mutect2, varscan2
- CPSF1 | c.1598A>G p.Y533C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as rs782797901, COSV100574664; called by muse, mutect2
- CPT1C | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99773528; called by muse, mutect2, varscan2
- CPVL | c.1251dup p.V418Sfs*6 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | catalogued as rs1371094883; called by mutect2, varscan2
- CRACR2A | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99365238; called by muse, mutect2, varscan2
- CRB2 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1335857752, COSV100749788, COSV63503943; called by muse, mutect2, varscan2
- CSRNP1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99826959; called by muse, mutect2, varscan2
- CTTN | c.724A>G p.R242G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1234766178, COSV100098005; called by muse, mutect2, varscan2
- CUX1 | c.1282G>C p.A428P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs782489323, COSV52895909; called by muse, mutect2, varscan2
- CUX1 | c.1664A>G p.Y555C (on ENST00000437600 / NM_181500.4; = p.Y557C on NM_001913.5) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52929073; called by muse, mutect2
- CWC27 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101126535; called by muse, mutect2, varscan2
- CXCR6 | c.778T>C p.Y260H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV99945915; called by muse, mutect2, varscan2
- CXXC4 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101182299; called by muse, mutect2, varscan2
- CYLC1 | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV61415383; called by muse, mutect2, varscan2
- CYP21A2 | c.183G>T p.R61S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV100926442; called by mutect2, varscan2
- DCAF1 | c.3459del p.A1154Lfs*13 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as COSV60042352; called by mutect2, pindel, varscan2
- DCAF4L2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs747761232, COSV60479886; called by muse, mutect2, varscan2
- DCDC1 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV60836779, COSV60849362; called by muse, mutect2, varscan2
- DCTPP1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); catalogued as rs143083714; called by muse, mutect2, varscan2
- DGKB | c.569G>T p.W190L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51776517, COSV99341182; called by muse, mutect2, varscan2
- DGLUCY | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99824493; called by muse, mutect2, varscan2
- DHTKD1 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV99536672; called by muse, mutect2, varscan2
- DHX9 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.832); catalogued as rs1302395270, COSV62362167; called by muse, mutect2, varscan2
- DICER1 | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58620687; called by muse, mutect2, varscan2
- DISP3 | c.2869C>A p.L957M | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.459); catalogued as COSV99609264; called by muse, mutect2, varscan2
- DLG5 | c.3719G>A p.C1240Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as rs1475237721, COSV100967638; called by muse, mutect2, varscan2
- DLGAP1 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100232443; called by muse, mutect2, varscan2
- DMRT2 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs775052048, COSV52401659; called by muse, mutect2, varscan2
- DNAH1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs1209292872, COSV101326410; called by muse, mutect2, varscan2
- DNAH10 | c.10130G>A p.R3377Q (on ENST00000409039; = p.R3316Q on NM_207437.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1261480055, COSV101292402; called by muse, mutect2, varscan2
- DNALI1 | c.751_753del p.E251del (on ENST00000296218; = p.E229del on NM_003462.5) | In Frame Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs749047646; called by pindel, varscan2
- DOCK10 | c.5120C>T p.A1707V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99290453; called by muse, mutect2, varscan2
- DOCK11 | c.3121G>T p.G1041* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV99354210; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK7 | c.3254T>C p.M1085T (on ENST00000635253 / NM_001367561.1; = p.M1054T on NM_033407.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1194483146, COSV99225097; called by muse, mutect2, varscan2
- DPYS | c.1227del p.G410Afs*30 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as COSV100037166; called by mutect2, varscan2
- DROSHA | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.086); catalogued as COSV100757709; called by muse, mutect2, varscan2
- DST | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100422460; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 17/31 reads (55%) | catalogued as rs772082432; called by mutect2, varscan2
- EEA1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as rs1232296171, COSV100467420, COSV59285253; called by muse, mutect2, varscan2
- EIPR1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as rs773102775, COSV101182202; called by muse, mutect2, varscan2
- EMC7 | c.353T>C p.M118T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs1027892905, COSV99854916; called by mutect2, varscan2
- EME2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs766989037, COSV99457194; called by muse, mutect2, varscan2
- EMILIN1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs751586097, COSV53154767, COSV99566373; called by muse, mutect2, varscan2
- EPOR | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV99710186; called by muse, mutect2, varscan2
- ERP29 | c.712_714del p.K238del | In Frame Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs1352097022; called by pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 50/54 reads (93%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRP2 | c.1219G>A p.A407T (on ENST00000565858 / NM_001365264.1; = p.A397T on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs774450234, COSV52172605; called by muse, mutect2, varscan2
- EVI5L | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99563325; called by muse, mutect2
- EXOC6 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99592176; called by muse, mutect2, varscan2
- FABP6 | c.170del p.G57Afs*4 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | catalogued as COSV67436622; called by mutect2, pindel, varscan2
- FAM135B | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.127); catalogued as rs756855727, COSV99425523; called by muse, mutect2, varscan2
- FAM135B | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99425525; called by muse, mutect2, varscan2
- FAM169A | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs138216772; called by mutect2, varscan2
- FAM234A | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV99395881; called by muse, mutect2, varscan2
- FAM3D | c.586-4_586-3dup | Splice Region (INS) | VAF 4/30 reads (13%) | catalogued as rs1559492634; called by mutect2, varscan2
- FAM47C | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.8); catalogued as rs1433951072, COSV63727228, COSV63729490; called by muse, mutect2, varscan2
- FAM83G | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525285; called by muse, mutect2, varscan2
- FAT1 | c.5630del p.P1877Lfs*20 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as COSV71676103; called by mutect2, pindel, varscan2
- FAT2 | c.9092T>C p.L3031S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943511; called by muse, mutect2
- FBLN1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as rs369461467; called by muse, mutect2, varscan2
- FBN3 | c.6999del p.R2335Afs*30 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs1316583053; called by mutect2, varscan2
- FBXO21 | c.1603C>T p.R535W (on ENST00000330622 / NM_033624.3; = p.R528W on NM_015002.3) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV100401801; called by muse, mutect2, varscan2
- FBXO22 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV100380606; called by muse, mutect2, varscan2
- FBXO4 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55851246; called by muse, mutect2, varscan2
- FBXW11 | c.372A>G p.P124= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as rs1018771995, COSV99440937; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs144178676; called by mutect2, varscan2
- FGGY | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368548108, COSV100365269; called by muse, mutect2, varscan2
- FKRP | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100586703; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXP1 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV59547627, COSV59549860, COSV59556517; called by muse, mutect2, varscan2
- FRA10AC1 | c.694del p.R232Efs*96 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs775948504; called by mutect2, varscan2
- GABRG3 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.148); catalogued as rs773191845, COSV61526310; called by muse, mutect2, varscan2
- GATA5 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99435981; called by muse, mutect2
- GDE1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs537541856, COSV62059313; called by muse, mutect2, varscan2
- GDF3 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs767298278, COSV100325331; called by muse, mutect2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs750227570; called by mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GNRH1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV99373646; called by muse, mutect2, varscan2
- GPC4 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100895525, COSV63696957; called by muse, mutect2, varscan2
- GPN3 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99959895; called by muse, mutect2, varscan2
- GPR35 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs760148943, COSV60578594; called by muse, mutect2, varscan2
- GPRIN3 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100310847; called by muse, mutect2, varscan2
- GPS1 | c.1045A>G p.K349E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV100136061; called by muse, mutect2, varscan2
- GPSM1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782715651, COSV61305341; called by muse, mutect2, varscan2
- GRAMD1C | c.1000A>T p.I334F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63982646; called by muse, mutect2, varscan2
- GREB1 | c.4514T>C p.L1505P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99303236; called by muse, mutect2, varscan2
- GRHL2 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99307362; called by muse, mutect2, varscan2
- GRK5 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs774000868, COSV100963142, COSV100963345; called by muse, mutect2, varscan2
- GRM7 | c.159del p.L54Cfs*46 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV63140513; called by mutect2, varscan2
- GSX1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57233854; called by muse, mutect2, varscan2
- GTF3C4 | c.1691del p.K564Rfs*18 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs1241168444, COSV64645321; called by mutect2, varscan2
- GUK1 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770258206, COSV100451746; called by muse, mutect2, varscan2
- HACD4 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101529961; called by muse, mutect2, varscan2
- HAS2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as COSV58262158; called by muse, mutect2, varscan2
- HAUS6 | c.2429G>A p.G810D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV100997868; called by muse, mutect2, varscan2
- HCCS | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100335771; called by mutect2, varscan2
- HDAC1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1445685048, COSV101000437; called by muse, mutect2, varscan2
- HEATR5B | c.5852C>T p.A1951V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762648818, COSV51861288; called by muse, mutect2, varscan2
- HECTD1 | c.4364C>T p.T1455M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1378455661, COSV67946305; called by muse, mutect2, varscan2
- HECW1 | c.3666del p.Y1223Tfs*45 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as COSV101224210, COSV67827592; called by mutect2, pindel, varscan2
- HELZ2 | c.4012C>T p.R1338C (on ENST00000467148 / NM_001037335.2; = p.R769C on NM_033405.3) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs767271876, COSV71297089; called by muse, mutect2
- HERC2 | c.13358C>T p.S4453L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs776359705, COSV55316185; called by muse, mutect2, varscan2
- HERC2 | c.8556A>G p.S2852= | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99875148; called by muse, mutect2, varscan2
- HGFAC | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV100123095, COSV100123369, COSV58748818; called by muse, mutect2, varscan2
- HIPK4 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs372254628; called by muse, mutect2, varscan2
- HPS5 | c.1106T>C p.L369P (on ENST00000349215 / NM_181507.2; = p.L255P on NM_007216.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV100752329; called by mutect2, varscan2
- HPSE | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.331); catalogued as COSV100264417, COSV60988050; called by muse, mutect2, varscan2
- HRH1 | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101229074; called by muse, mutect2, varscan2
- HS3ST2 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs145617070, COSV54461631; called by muse, mutect2, varscan2
- HSD17B3 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100931284; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- HSPA6 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as rs747352949, COSV100554209; called by muse, mutect2, varscan2
- HTRA3 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100246426; called by muse, mutect2, varscan2
- IFT140 | c.4207C>T p.R1403W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs772400580, COSV51975827; called by muse, mutect2, varscan2
- IFT172 | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV99562819; called by muse, mutect2, varscan2
- IKZF3 | c.516del p.K172Nfs*88 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as COSV53105248; called by mutect2, pindel, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 27/57 reads (47%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ING1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58170934; called by muse, mutect2, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs762875806; called by mutect2, varscan2
- INTS1 | c.4791del p.K1598Sfs*21 | Frame Shift Del (DEL) | VAF 5/8 reads (63%) | catalogued as rs1562490038; called by mutect2, varscan2
- INTS6L | c.359dup p.L120Ffs*37 | Frame Shift Ins (INS) | VAF 28/63 reads (44%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQCE | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs776206111, COSV58077035; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGA10 | c.1633del p.Q545Rfs*15 | Frame Shift Del (DEL) | VAF 37/105 reads (35%) | catalogued as rs781882827; called by mutect2, pindel, varscan2
- ITGAL | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs751825408, COSV63322806; called by muse, varscan2
- ITGB8 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV99751842; called by muse, mutect2
- JAK2 | c.2240G>A p.C747Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV101076090; called by muse, mutect2, varscan2
- JCAD | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs749221379, COSV100948468; called by muse, mutect2, varscan2
- JPH2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV100881767; called by muse, mutect2, varscan2
- KANK4 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100587526; called by muse, mutect2, varscan2
- KCNC2 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54368089; called by muse, mutect2, varscan2
- KCNJ5 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389808024, COSV57970792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ3 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101196182, COSV101196255; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs754600318; called by mutect2, varscan2
- KIAA1549L | c.1304C>T p.T435I (on ENST00000321505; = p.T732I on NM_012194.3) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.146); catalogued as COSV99683880; called by muse, mutect2, varscan2
- KIF3A | c.1687C>A p.L563I | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV101109430; called by muse, mutect2, varscan2
- KIFC2 | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV100023892; called by muse, mutect2, varscan2
- KLF12 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs777273071, COSV100888544, COSV66577155; called by muse, mutect2, varscan2
- KLF9 | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009597; called by muse, mutect2
- KRT2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); catalogued as rs530180060, COSV59008994; called by muse, mutect2, varscan2
- KRT74 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779011687, COSV99977587; called by muse, mutect2, varscan2
- LARS1 | c.3053C>T p.A1018V (on ENST00000394434 / NM_020117.11; = p.A991V on NM_016460.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99198684; called by muse, mutect2, varscan2
- LCP1 | c.1201A>G p.R401G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549975; called by muse, mutect2, varscan2
- LCT | c.5740A>G p.T1914A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99739360; called by muse, mutect2
- LCTL | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100328782; called by muse, mutect2, varscan2
- LDLR | c.892A>G p.M298V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs730882092, COSV99370104; ClinVar: not provided; called by muse, mutect2
- LILRB3 | c.1439G>A p.R480H (on ENST00000346401; = p.R468H on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs746731531, COSV99558018; called by muse, mutect2, varscan2
- LITAF | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100243181; called by muse, mutect2, varscan2
- LPAR2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs961983676, COSV99179370; called by muse, mutect2, varscan2
- LRP1 | c.3485C>T p.P1162L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as COSV99676470; called by muse, mutect2, varscan2
- LRRC14 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765442195, COSV99467846; called by muse, mutect2, varscan2
- LRRC15 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.14); catalogued as rs372164095; called by muse, mutect2, varscan2
- LRRC8C | c.1524dup p.W509Lfs*20 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | catalogued as rs762972819; called by mutect2, varscan2
- LRRC8E | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143034; called by muse, mutect2, varscan2
- LRRK1 | c.276C>A p.S92R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99441368; called by muse, mutect2
- LSM14A | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.469); catalogued as rs147367720; called by muse, mutect2, varscan2
- LUC7L2 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV99693226; called by muse, mutect2
- LUZP2 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100420428; called by mutect2, varscan2
- LZTS2 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV100932239; called by muse, varscan2
- LZTS2 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.547); catalogued as rs764904227, COSV64651159; called by muse, mutect2, varscan2
- MACF1 | c.18803del p.N6268Mfs*32 (on ENST00000372915; = p.N4313Mfs*32 on NM_012090.5) | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs748961150; called by pindel, varscan2
- MAN2A1 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99811468; called by muse, mutect2, varscan2
- MAN2A2 | c.1582del p.X528_splice | Splice Site (DEL) | VAF 19/52 reads (37%) | catalogued as rs1219552862; called by mutect2, pindel, varscan2
- MAN2B1 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99667123; called by muse, mutect2, varscan2
- MANSC1 | c.1197A>G p.I399M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101115866; called by muse, mutect2, varscan2
- MAP2 | c.4420dup p.T1474Nfs*22 | Frame Shift Ins (INS) | VAF 26/31 reads (84%) | catalogued as rs1476495251; called by mutect2, varscan2
- MAP4K5 | c.793del p.R265Dfs*8 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs746424357; called by mutect2, varscan2
- MAPK8IP3 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99169346; called by muse, mutect2, varscan2
- MARK4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1443710354, COSV99488492; called by muse, mutect2, varscan2
- MBD1 | c.516+2T>C p.X172_splice | Splice Site (SNP) | VAF 23/46 reads (50%) | catalogued as COSV99496692; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs558765093; called by mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | catalogued as rs746267361; called by mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs1180255648; called by mutect2, varscan2
- MED12 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs374780236, COSV100378835; ClinVar: uncertain significance; called by mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MFSD2B | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs367771310, COSV100601226; called by muse, mutect2, varscan2
- MGAT4C | c.336del p.G113Efs*20 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | catalogued as rs1347429614; called by mutect2, varscan2
- MICAL1 | c.2002C>A p.P668T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99238042; called by muse, varscan2
- MICAL3 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs2289719; called by muse, varscan2
- MKS1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99836631; called by muse, mutect2, varscan2
- MLF1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as rs141212572; called by muse, mutect2, varscan2
- MMRN2 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64400704; called by muse, mutect2, varscan2
- MMS22L | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99247311; called by muse, mutect2
- MOGS | c.881del p.P294Lfs*11 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs750486813; called by mutect2, pindel, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs753079987; called by mutect2, varscan2
- MRPL38 | c.771del p.F258Sfs*54 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs758439223; called by mutect2, pindel, varscan2
- MRPS11 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100363771; called by muse, mutect2, varscan2
- MYH2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1303315952, COSV55435569; called by muse, mutect2, varscan2
- MYH3 | c.5035G>T p.A1679S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV99878490; called by muse, mutect2, varscan2
- MYH6 | c.1793del p.N598Tfs*63 | Frame Shift Del (DEL) | VAF 49/124 reads (40%) | catalogued as COSV100676665; called by mutect2, pindel, varscan2
- MYH7 | c.3845C>T p.T1282I | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100806302; called by muse, mutect2, varscan2
- MYOD1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100000248; called by muse, mutect2, varscan2
- MYOM3 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs552442304, COSV100293217; called by muse, mutect2, varscan2
- MYRF | c.435G>T p.E145D (on ENST00000278836 / NM_001127392.3; = p.E136D on NM_013279.4) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV99607399; called by muse, mutect2, varscan2
- NAA16 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101050027; called by muse, mutect2, varscan2
- NAF1 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV56803699; called by muse, mutect2, varscan2
- NAF1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs751378645, COSV99919237; called by muse, mutect2, varscan2
- NAV3 | c.1216G>T p.G406* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | catalogued as COSV57090272; called by muse, mutect2, varscan2
- NCL | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1439517514, COSV100502406; called by muse, mutect2, varscan2
- NCOR1 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754792931, COSV99250807; called by muse, varscan2
- NCOR2 | c.2956del p.R986Gfs*77 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs746871841; called by pindel, varscan2
- NEIL3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs114671957; called by muse, mutect2, varscan2
- NELFCD | c.791del p.G264Afs*27 (on ENST00000602795; = p.G246Afs*27 on NM_198976.4) | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs920632659; called by mutect2, pindel, varscan2
- NET1 | c.1735C>T p.R579* (on ENST00000355029 / NM_001047160.3; = p.R525* on NM_005863.5) | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs926523708, COSV100742326; called by muse, mutect2, varscan2
- NFKB1 | c.1676T>C p.V559A (on ENST00000394820 / NM_001382627.1; = p.V560A on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV99897505; called by muse, mutect2, varscan2
- NFRKB | c.863T>C p.M288T (on ENST00000446488 / NM_001143835.2; = p.M313T on NM_006165.3) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV100452005; called by muse, mutect2, varscan2
- NLGN4X | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320884, COSV99322774; called by muse, mutect2, varscan2
- NOC4L | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1271257759, COSV57960541; called by muse, mutect2, varscan2
- NOL10 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs368376128, COSV62040457; called by muse, mutect2, varscan2
- NOS1 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769905102, COSV57613331; called by muse, mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs746543323; called by mutect2, pindel, varscan2
- NOTCH3 | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs150338460, COSV99657946; called by muse, mutect2, varscan2
- NOTCH3 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99657951; called by muse, mutect2, varscan2
- NUBP2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as rs749655410, COSV99236589; called by muse, mutect2
- NUDT5 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100968813; called by muse, mutect2, varscan2
- NUF2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs747173543, COSV54841988; called by muse, mutect2, varscan2
- NVL | c.199A>G p.S67G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99894667; called by muse, mutect2, varscan2
- ODF2 | c.1240G>A p.E414K (on ENST00000434106 / NM_153433.2; = p.E390K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs1008126433, COSV100654494, COSV63548536; called by muse, mutect2, varscan2
- OGA | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.445); catalogued as COSV100761905; called by muse, mutect2, varscan2
- OGFOD2 | c.934G>A p.V312M (on ENST00000228922 / NM_001304833.1; = p.V252M on NM_024623.3) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99759279; called by muse, mutect2, varscan2
- OGFOD3 | c.883T>C p.W295R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV100234461; called by muse, mutect2, varscan2
- OGFOD3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as rs761987026, COSV100027826; called by muse, mutect2, varscan2
- OR10A5 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100203535, COSV55055582; called by muse, mutect2, varscan2
- OR10W1 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV101223623; called by muse, mutect2, varscan2
- OR14K1 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99315126; called by muse, mutect2, varscan2
- OR2AE1 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as rs747366191, COSV100318329; called by muse, mutect2, varscan2
- OTUD7A | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs772302638, COSV61040789; called by muse, mutect2, varscan2
- P4HTM | c.1183G>A p.V395M (on ENST00000383729 / NM_177939.3; = p.V456M on NM_177938.2) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs374563891; called by muse, mutect2, varscan2
- PACSIN2 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1569232586, COSV54319719; called by mutect2, varscan2
- PADI1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs756516910, COSV100968970, COSV64937925; called by muse, mutect2
- PADI6 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs747550335, COSV100639967; called by muse, mutect2, varscan2
- PANX1 | c.330dup p.Y111Lfs*37 | Frame Shift Ins (INS) | VAF 20/41 reads (49%) | catalogued as COSV99921902; called by mutect2, pindel, varscan2
- PARD3 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100401420; called by muse, mutect2, varscan2
- PASD1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs375505833, COSV100949453; called by muse, mutect2, varscan2
- PAX5 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1337956293, COSV100814408; called by muse, mutect2, varscan2
- PBX4 | c.1063del p.Q355Nfs*25 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs748202447; called by mutect2, pindel, varscan2
- PCDHA9 | c.2305C>A p.L769I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV100969800; called by muse, mutect2, varscan2
- PCDHAC1 | c.2614G>A p.G872S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs781996586, COSV53866911; called by muse, mutect2, varscan2
- PCDHB8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs1483942587, COSV50753538; called by muse, mutect2, varscan2
- PCDHGA11 | c.1498dup p.V500Gfs*10 | Frame Shift Ins (INS) | VAF 19/52 reads (37%) | catalogued as rs1048315821; called by mutect2, pindel, varscan2
- PCDHGB3 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs569737317, COSV53912080; called by muse, mutect2, varscan2
- PCDHGB3 | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV99541951; called by muse, mutect2, varscan2
- PDE10A | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100605316; called by muse, varscan2
- PDE4DIP | c.200A>G p.Q67R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100520310; called by muse, mutect2, varscan2
- PDPR | c.1464del p.D489Tfs*46 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs778706893; called by pindel, varscan2
- PDS5B | c.4211A>G p.N1404S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV59729305; called by muse, mutect2, varscan2
- PDZD4 | c.1304T>C p.L435P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs945102737, COSV99381486; called by muse, mutect2, varscan2
- PDZRN3 | c.761G>C p.R254P | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99730752; called by muse, mutect2, varscan2
- PELI3 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV100291835; called by muse, mutect2
- PEPD | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200871513, COSV99728290; called by muse, mutect2, varscan2
- PFKFB4 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | PolyPhen benign (0.073); catalogued as COSV99219792; called by muse, mutect2, varscan2
- PGBD1 | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99460602; called by muse, mutect2
- PGK1 | c.65+2T>C p.X22_splice | Splice Site (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100965349; called by muse, mutect2, varscan2
- PHF20 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772978047, COSV100179955; called by muse, mutect2, varscan2
- PHLDB1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs782664892, COSV100616646; called by muse, mutect2, varscan2
- PIAS4 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV99518966; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs756552559; called by mutect2, varscan2
- PIPOX | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1009541197, COSV60142586; called by muse, mutect2, varscan2
- PIWIL4 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs185092971; called by muse, mutect2, varscan2
- PKP4 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200994124, COSV67678569; called by muse, mutect2, varscan2
- PLCH2 | c.3746C>A p.P1249H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); catalogued as COSV99616684; called by muse, mutect2, varscan2
- PLCL2 | c.1346A>G p.Q449R (on ENST00000615277 / NM_001144382.2; = p.Q323R on NM_015184.5) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV101196850; called by muse, mutect2, varscan2
- PLEC | c.10819G>A p.A3607T (on ENST00000322810 / NM_201380.4; = p.A3497T on NM_000445.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs377602333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POFUT1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs745383992, COSV65337185; called by muse, mutect2, varscan2
- POLR2H | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954899; called by muse, mutect2, varscan2
- POMT1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs772590277, COSV61228264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIA3 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100495065; called by muse, mutect2, varscan2
- PPM1A | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100349244; called by muse, mutect2
- PPP1R18 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs1461717612, COSV51295219, COSV99223786; called by muse, mutect2, varscan2
- PPP1R3A | c.2065del p.R689Efs*7 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs753380860; called by mutect2, pindel, varscan2
- PPP2R2B | c.961-2A>G p.X321_splice (on ENST00000394409; = p.X387_splice on NM_181674.2) | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV60766202; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs540232176; called by mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 28/64 reads (44%) | catalogued as rs768056539; called by mutect2, varscan2
- PPRC1 | c.4930A>G p.S1644G | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1324191449, COSV99531813; called by muse, mutect2, varscan2
- PRB4 | c.311del p.P104Hfs*153 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | catalogued as rs1369639961; called by pindel, varscan2
- PRDM2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs776791719, COSV99342182; called by muse, mutect2, varscan2
- PRICKLE3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs782690118, COSV54294547; called by muse, mutect2, varscan2
- PRIM1 | c.105G>A p.V35= | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100590428; called by muse, mutect2, varscan2
- PRKACG | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55253192, COSV99599282; called by muse, mutect2, varscan2
- PRKAG2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.021); catalogued as COSV99835594; called by muse, mutect2, varscan2
- PRLR | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV51497373; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs760446387; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | catalogued as rs781858060; called by mutect2, varscan2
- PRUNE2 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV65037929, COSV65038743; called by muse, mutect2, varscan2
- PTEN | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1064794436, COSV64291569, COSV64310183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN2 | c.704T>G p.L235W | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518658; called by muse, mutect2
- PTPN6 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100017186; called by muse, mutect2, varscan2
- PTPRD | c.4391A>G p.K1464R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100643596, COSV100645554; called by muse, mutect2, varscan2
- QDPR | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs865953344, COSV99845890; called by muse, mutect2, varscan2
- QSOX1 | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 51/95 reads (54%) | catalogued as COSV62581436; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RAB39A | c.149_151del p.F50del | In Frame Del (DEL) | VAF 19/37 reads (51%) | catalogued as rs1301461645; called by pindel, varscan2
- RADIL | c.1286del p.G429Afs*6 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs768989877; called by mutect2, pindel, varscan2
- RANBP17 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101206337; called by muse, mutect2, varscan2
- RASGEF1A | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs753375542, COSV100988694; called by muse, mutect2, varscan2
- RB1CC1 | c.997A>C p.S333R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV99212466; called by muse, mutect2, varscan2
- RBL2 | c.2780A>G p.Y927C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100043839; called by muse, mutect2
- RBM10 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as COSV100238020; called by muse, mutect2, varscan2
- RBM23 | c.809T>C p.L270P (on ENST00000359890 / NM_001077351.2; = p.L254P on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100321449; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs762006287; called by mutect2, varscan2
- REC8 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs748399051, COSV61018275; called by muse, mutect2, varscan2
- RECQL4 | c.3321C>G p.Y1107* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs376392965; called by mutect2, varscan2
- RGS20 | c.319del p.L107Cfs*41 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs747974681; called by mutect2, varscan2
- RHOBTB1 | c.1828C>A p.H610N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100558573; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RIC8B | c.834C>T p.H278= | Splice Region (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100822669; called by muse, mutect2, varscan2
- RIT2 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56306812, COSV99951309; called by muse, mutect2
- RMND5B | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs138151996; called by muse, mutect2, varscan2
- RNASEH2A | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs1033081366, COSV55551783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF111 | c.1442G>A p.C481Y | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100789108; called by muse, mutect2, varscan2
- RNF113A | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.453); catalogued as rs781318480, COSV101007075; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPAP1 | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs866714971, COSV58537132; called by muse, mutect2, varscan2
- RPL11 | c.6G>A p.A2= | Splice Region (SNP) | VAF 14/25 reads (56%) | catalogued as COSV100999678; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPLP0 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV99935419; called by muse, mutect2, varscan2
- RPS6KA6 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53129532; called by muse, mutect2, varscan2
- RPS6KL1 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100665146; called by muse, mutect2, varscan2
- RPTOR | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156688; called by muse, mutect2, varscan2
- RTL3 | c.712dup p.L238Pfs*16 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as rs772223607; called by mutect2, pindel, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs747510098; called by mutect2, varscan2
- RTP5 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV100574768; called by muse, mutect2, varscan2
- RYR2 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.59); catalogued as rs370057029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.4928A>T p.E1643V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100771751; called by muse, varscan2
- S1PR1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as CM1413471; called by muse, mutect2, varscan2
- SART1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs538739713, COSV100409072; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs757259031; called by mutect2, varscan2
- SCARF2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs369860412; called by muse, mutect2, varscan2
- SCNM1 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99766241; called by mutect2, varscan2
- SCRIB | c.3209C>T p.T1070M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781978489, COSV57590890; called by muse, mutect2, varscan2
- SEC16A | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as rs1355797721, COSV99259291; called by muse, mutect2, varscan2
- SEC23IP | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100956949; called by muse, mutect2, varscan2
- SEC31A | c.3247A>G p.N1083D (on ENST00000355196 / NM_001318120.1; = p.N1044D on NM_016211.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.118); catalogued as rs1310582614, COSV100022114; called by muse, mutect2, varscan2
- SEC63 | c.1586del p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 28/61 reads (46%) | catalogued as rs758487924; called by mutect2, varscan2
- SELENOK | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs376660375, COSV59832341; called by muse, mutect2
- SEMA3A | c.1495-1G>A p.X499_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99547326, COSV99548155; called by muse, mutect2, varscan2
- SEMA6B | c.826del p.R276Afs*11 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs781437207, COSV56702141, COSV56702780; called by mutect2, pindel, varscan2
- SEPTIN6 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100595687; called by muse, mutect2, varscan2
- SERBP1 | c.755C>T p.S252L (on ENST00000370995 / NM_001018067.2; = p.S231L on NM_015640.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs1481670235, COSV100769136; called by muse, mutect2, varscan2
- SETD5 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs748495610, COSV56711853; called by muse, mutect2, varscan2
- SFTPB | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100667250; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs746556543; called by mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHROOM4 | c.2903C>A p.P968H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99173844; called by muse, mutect2, varscan2
- SIPA1L2 | c.1591T>A p.Y531N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99478931; called by muse, mutect2, varscan2
- SLAIN1 | c.937T>C p.C313R (on ENST00000466548; = p.C50R on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV57390457, COSV99935396; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | catalogued as rs751442558; called by mutect2, varscan2
- SLAMF1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs757836091, COSV52499313; called by muse, mutect2, varscan2
- SLC24A4 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV100105581; called by muse, mutect2, varscan2
- SLC32A1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as rs1414811807, COSV54147503; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC4A10 | c.1703G>A p.S568N (on ENST00000446997 / NM_001354461.2; = p.S538N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99764817; called by muse, mutect2, varscan2
- SLC5A10 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs777239029, COSV100525283; called by muse, mutect2, varscan2
- SLIT3 | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100268672; called by muse, mutect2, varscan2
- SMARCA4 | c.3762G>T p.E1254D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100758792; called by muse, mutect2, varscan2
- SMARCC2 | c.3349C>T p.H1117Y | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99519480; called by muse, mutect2, varscan2
- SOX15 | c.498del p.S167Afs*64 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | catalogued as rs1214200459; called by mutect2, pindel, varscan2
- SOX7 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100449123; called by muse, mutect2, varscan2
- SP4 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as rs1305715394, COSV56021999; called by muse, mutect2, varscan2
- SPINT2 | c.626T>C p.L209S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100007602; called by muse, mutect2, varscan2
- SPNS1 | c.815G>C p.S272T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100209149; called by muse, varscan2
- SPRTN | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs752112777, COSV99149906; called by muse, varscan2
- SPTBN1 | c.3173T>C p.L1058P | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442999; called by muse, mutect2, varscan2
- SRP68 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753777388, COSV100326177; called by muse, mutect2, varscan2
- SRRM4 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs759788629, COSV99938834; called by muse, varscan2
- SRSF4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441731561, COSV65695639; called by muse, varscan2
- STAB1 | c.4015del p.V1339Cfs*252 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs761841917, COSV100402435; called by mutect2, pindel, varscan2
- STAMBPL1 | c.1272G>T p.L424F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.052); catalogued as COSV100904970; called by muse, mutect2, varscan2
- STARD8 | c.2957del p.X986_splice | Splice Site (DEL) | VAF 12/42 reads (29%) | catalogued as COSV99366452; called by mutect2, pindel, varscan2
- STK11IP | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs906299774, COSV99823087; called by muse, mutect2, varscan2
- STPG2 | c.611del p.K204Rfs*6 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs778953320; called by mutect2, varscan2
- STS | c.1475A>G p.H492R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99481435; called by muse, mutect2, varscan2
- SUMF2 | c.800G>C p.G267A (on ENST00000652303; = p.R296= on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV99305225; called by muse, mutect2, varscan2
- SUSD2 | c.1669del p.D557Tfs*22 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as COSV64205163; called by pindel, varscan2
- SUSD2 | c.1724G>A p.G575D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV100844366; called by muse, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SVIL | c.2054A>G p.K685R (on ENST00000355867 / NM_021738.3; = p.K291R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100881400; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.25369G>T p.G8457W (on ENST00000367255 / NM_182961.4; = p.G8409W on NM_033071.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99571122; called by muse, mutect2, varscan2
- TAF1L | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as COSV99644982; called by muse, mutect2, varscan2
- TAFA2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485194609, COSV69178650; called by muse, mutect2, varscan2
- TAS1R2 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.249); catalogued as COSV100946276; called by muse, mutect2, varscan2
- TAS2R41 | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV101281499; called by muse, mutect2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs757209781; called by mutect2, varscan2
- TBC1D8 | c.2567T>C p.I856T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs368734566; called by mutect2, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | catalogued as rs748952707, COSV56876494; called by mutect2, pindel, varscan2
- TECPR2 | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142102340; called by muse, mutect2, varscan2
- TENT5B | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs1331117019, COSV100006680, COSV56692447; called by muse, mutect2, varscan2
- TEX15 | c.4624_4626del p.K1542del (on ENST00000256246; = p.K1925del on NM_001350162.2) | In Frame Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs1563235232; called by pindel, varscan2
- TICAM1 | c.1868C>T p.T623I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as rs113327885; called by muse, mutect2, varscan2
- TJP3 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770165052, COSV99516292; called by muse, mutect2, varscan2
- TM4SF4 | c.60dup p.G21Wfs*5 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs776266010; called by mutect2, varscan2
- TMCC2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs536038933, COSV100319442; called by muse, mutect2, varscan2
- TMED8 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.131); catalogued as rs746624938, COSV99375064; called by muse, mutect2, varscan2
- TMEM190 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as COSV99404329; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 48/53 reads (91%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS11A | c.143del p.K48Rfs*11 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs763235501; called by mutect2, pindel, varscan2
- TMTC3 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99898501; called by muse, mutect2, varscan2
- TNFRSF10D | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441811; called by muse, mutect2, varscan2
- TNFRSF8 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV99821691; called by muse, mutect2, varscan2
- TNRC18 | c.2564C>T p.S855L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs370482141; called by muse, mutect2, varscan2
- TPGS2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528870; called by muse, mutect2
- TRAPPC11 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs368097747; called by muse, mutect2, varscan2
- TRIM65 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99485520; called by muse, varscan2
- TRIM65 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as rs1333685849, COSV99485521; called by muse, varscan2
- TRMT61A | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100149405; called by muse, mutect2, varscan2
- TRPM8 | c.2301del p.E768Sfs*16 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as rs770879940; called by mutect2, pindel, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs752121179, COSV54531581; called by mutect2, pindel, varscan2
- TSSK1B | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs370311657; called by muse, mutect2, varscan2
- TTC9 | c.282del p.E96Nfs*15 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs751516988; called by mutect2, pindel
- TTN | c.5783A>T p.E1928V (on ENST00000591111; = p.E1882V on NM_003319.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | PolyPhen probably damaging (0.998); catalogued as COSV100620299; called by muse, mutect2, varscan2
- TTYH3 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs202173699, COSV99349980; called by muse, mutect2, varscan2
- TUBB2A | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61319181; called by muse, mutect2, varscan2
- TXLNB | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs963968093, COSV64443344; called by muse, mutect2
- UBAP2 | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs779941549, COSV99602332; called by muse, mutect2, varscan2
- UBIAD1 | c.707A>T p.D236V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954910; called by muse, mutect2, varscan2
- UBR4 | c.7054A>G p.M2352V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100921276; called by muse, mutect2, varscan2
- ULK4 | c.3319C>G p.L1107V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100093699; called by muse, varscan2
- ULK4 | c.1778del p.K593Rfs*17 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs76318575; called by mutect2, varscan2
- UNC13B | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs745505422, COSV101036638; called by muse, mutect2, varscan2
- UNC5C | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101497953; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs767420916; called by mutect2, varscan2
- USP21 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as rs779217194, COSV99237601; called by muse, mutect2, varscan2
- USP4 | c.1324A>G p.R442G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753466684, COSV99649477; called by muse, varscan2
- UST | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as COSV66545507; called by muse, mutect2, varscan2
- VAC14 | c.2299C>A p.H767N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.177); catalogued as COSV99934168, COSV99934829; called by muse, mutect2, varscan2
- VARS2 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1244836047, COSV58913691, COSV58914684; called by muse, mutect2, varscan2
- VEZT | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1274418107, COSV54143526, COSV99704074; called by muse, mutect2, varscan2
- VHL | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs199926195, COSV56547487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS54 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99708399; called by muse, mutect2, varscan2
- VWA8 | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271414675, COSV99864542; called by muse, mutect2, varscan2
- WDR33 | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs1421671773, COSV100460340; called by muse, mutect2, varscan2
- WDR77 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV99330888; called by muse, mutect2, varscan2
- WNK2 | c.2891del p.P964Lfs*150 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as COSV52930875; called by mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 14/22 reads (64%) | catalogued as rs771899177; called by mutect2, varscan2
- XAB2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs781412220, COSV100222062; called by muse, mutect2, varscan2
- XIRP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs145421741; called by muse, mutect2, varscan2
- YTHDC2 | c.4280dup p.N1427Kfs*4 | Frame Shift Ins (INS) | VAF 18/34 reads (53%) | catalogued as rs758162743; called by mutect2, varscan2
- ZC3H12A | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1296932581, COSV66104448; called by muse, mutect2
- ZCCHC7 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as rs1177158416, COSV100383288; called by muse, varscan2
- ZDHHC17 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100602183; called by muse, varscan2
- ZFYVE28 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747879895, COSV99343215; called by muse, varscan2
- ZFYVE9 | c.2155C>T p.H719Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99820346; called by muse, mutect2, varscan2
- ZHX3 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100476367; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs1385093153, COSV99357027; called by muse, mutect2, varscan2
- ZMYM3 | c.734G>T p.R245I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100078109; called by muse, mutect2, varscan2
- ZNF169 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100566296; called by muse, mutect2, varscan2
- ZNF34 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58639629; called by muse, mutect2
- ZNF493 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.163); catalogued as COSV100828780; called by muse, varscan2
- ZNF540 | c.843dup p.S282* | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as rs757107073; called by mutect2, varscan2
- ZNF595 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); catalogued as COSV100227806; called by muse, mutect2, varscan2
- ZNF618 | c.835G>A p.A279T (on ENST00000374126 / NM_001318042.2; = p.A267T on NM_133374.2) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.251); catalogued as rs756019150, COSV55923061; called by muse, mutect2, varscan2
- ZNF721 | c.1580G>A p.R527K (on ENST00000338977; = p.R539K on NM_133474.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.92); catalogued as COSV100167540; called by mutect2, varscan2
- ZNF93 | c.513dup p.P172Tfs*12 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs775444781; called by mutect2, varscan2
- ZNRF3 | c.1229C>T p.P410L (on ENST00000544604 / NM_001206998.2; = p.P310L on NM_032173.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs779789745, COSV100238069, COSV100238694, COSV60433507; called by muse, mutect2, varscan2
- ZSCAN2 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142869560; called by muse, mutect2, varscan2
- ZZEF1 | c.7931G>A p.S2644N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV101067919; called by muse, mutect2, varscan2
- AARS1 | c.817-6_817-3del | Splice Region (DEL) | VAF 27/48 reads (56%) | called by mutect2, pindel, varscan2
- ACACA | c.5011T>C p.Y1671H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ACAD10 | c.1077del p.F360Sfs*3 | Frame Shift Del (DEL) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- AKAP13 | c.7511del p.K2504Rfs*50 (on ENST00000394518 / NM_007200.5; = p.K2508Rfs*50 on NM_006738.6) | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.347del p.P116Lfs*11 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- ALG9 | c.1456C>T p.Q486* (on ENST00000614444 / NM_001352418.1; = p.Q493* on NM_024740.2) | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- ANK1 | c.1873_1874insT p.G625Vfs*168 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- APOBEC3B | c.288del p.C97Afs*20 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- ARHGAP28 | c.1298del p.R433Lfs*25 (on ENST00000383472 / NM_001366230.1; = p.R274Lfs*25 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.3332del p.P1111Lfs*5 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ASH1L | c.8816dup p.N2939Kfs*4 (on ENST00000368346 / NM_001366177.2; = p.N2934Kfs*4 on NM_018489.3) | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- BCL2L2 | c.269del p.G90Afs*8 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by pindel, varscan2
- C11orf16 | c.340del p.V114Sfs*25 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- CARD6 | c.1314del p.P439Lfs*9 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- CASP8 | c.1380dup p.K461Efs*19 (on ENST00000432109 / NM_033355.3; = p.K478Efs*19 on NM_001228.4) | Frame Shift Ins (INS) | VAF 14/27 reads (52%) | called by mutect2, pindel, varscan2
- CCDC170 | c.1859_1862del p.E620Gfs*5 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by pindel, varscan2
- CCNF | c.1746_1747del p.G583Qfs*33 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- CDC37L1 | c.173_176del p.K58Sfs*3 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- CLEC18B | c.669del p.L224Sfs*11 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | called by mutect2, pindel, varscan2
- CPA5 | c.1101del p.F367Lfs*66 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- CSTF3 | c.210_211del p.Y71Hfs*2 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- CUL1 | c.1128del p.K376Nfs*6 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- CUL2 | c.194dup p.L65Ffs*10 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, varscan2
- DBH | c.1489del p.Q497Rfs*56 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- DCAF4L1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DENND4B | c.-2_16delinsGCCATGGCGGAGGAGCGG | Translation Start Site (ONP) | VAF 7/26 reads (27%) | called by pindel, varscan2*
- DLST | c.527del p.P176Lfs*27 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- FAM214B | c.1002del p.S335Vfs*77 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | called by mutect2, varscan2
- FCHO2 | c.1363_1364del p.L455Ffs*26 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by pindel, varscan2
- FPR3 | c.879dup p.N294* | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.3144del p.K1048Nfs*29 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- GFOD2 | c.701_702del p.C234* | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by pindel, varscan2
- GPR179 | c.3272C>T p.A1091V (on ENST00000621958; = p.A1090V on NM_001004334.4) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSPT2 | c.737dup p.N246Kfs*22 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | called by mutect2, varscan2
- HERC2 | c.8220dup p.H2741Tfs*12 | Frame Shift Ins (INS) | VAF 57/197 reads (29%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.1206del p.K402Nfs*21 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- HNRNPLL | c.252_253del p.C84* | Nonsense Mutation (DEL) | VAF 8/22 reads (36%) | called by pindel, varscan2
- HOOK3 | c.1637dup p.K547Efs*3 | Frame Shift Ins (INS) | VAF 4/19 reads (21%) | called by pindel, varscan2
- HRC | c.71del p.P24Rfs*3 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- IFI16 | c.1115del p.K372Rfs*7 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- IRF6 | c.1024_1026del p.K342del | In Frame Del (DEL) | VAF 10/26 reads (38%) | called by pindel, varscan2
- KCNRG | c.470del p.F157Sfs*5 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.1228del p.R410Efs*56 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | called by mutect2, pindel, varscan2
- KIF11 | c.1116del p.A373Lfs*10 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- KIF13A | c.2295del p.V766Ffs*39 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- KIF3C | c.996del p.N333Mfs*7 | Frame Shift Del (DEL) | VAF 32/62 reads (52%) | called by mutect2, varscan2
- KLHL17 | c.1751del p.G584Vfs*100 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- KMT2B | c.5361del p.P1788Rfs*107 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- LAMA2 | c.8953del p.M2985Wfs*8 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- LIMK1 | c.1730del p.P577Rfs*22 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- LMAN1 | c.911_912del p.K304Rfs*20 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, varscan2
- LMTK3 | c.3594del p.K1199Sfs*117 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- LRRC3 | c.439del p.L147Cfs*14 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- MAGED1 | c.1844+3_1844+6del p.X615_splice | Splice Site (DEL) | VAF 19/45 reads (42%) | called by pindel, varscan2
- MAGEL2 | c.2587del p.Q863Rfs*41 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | called by mutect2, pindel, varscan2
- MAST2 | c.2178del p.F726Lfs*12 | Frame Shift Del (DEL) | VAF 42/96 reads (44%) | called by mutect2, pindel, varscan2
- MED14 | c.216-9_242+11delinsCTTCTTAGACTGCCAAGGAAATCTGATGTGGAAAGGTGAGTATGG p.X72_splice | Splice Site (DEL) | VAF 3/30 reads (10%) | called by pindel, varscan2*
- MNT | c.1113del p.S372Afs*84 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- MORC4 | c.532del p.M178* | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- MUC4 | c.12852dup p.T4285Hfs*29 (on ENST00000463781 / NM_018406.7; = p.T49Hfs*29 on NM_004532.6) | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- MYL12A | c.449del p.K150Rfs*13 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- NAV2 | c.2955_2956del p.R986Kfs*8 (on ENST00000396087 / NM_001244963.2; = p.R963Kfs*8 on NM_145117.5) | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by pindel, varscan2
- NCOR2 | c.4559del p.G1520Afs*22 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- NLRP7 | c.2938del p.C980Afs*32 (on ENST00000340844 / NM_206828.3; = p.C1009Afs*32 on NM_139176.3) | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- NOG | c.635del p.G212Afs*52 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- NTN3 | c.602del p.P201Qfs*15 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- NUP54 | c.91_93del p.T31del | In Frame Del (DEL) | VAF 6/21 reads (29%) | called by pindel, varscan2
- OSBPL6 | c.327del p.F109Lfs*8 | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- OTOR | c.186del p.Q64Sfs*10 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- OXA1L | c.345_348del p.F115Lfs*47 (on ENST00000285848; = p.F55Lfs*47 on NM_005015.5) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGB1 | c.2318del p.P773Lfs*74 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, pindel, varscan2
- PDZD8 | c.2637dup p.C880Mfs*8 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- PGR | c.1853del p.N618Tfs*31 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- PIH1D2 | c.377del p.N126Ifs*3 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | called by mutect2, varscan2
- PKHD1L1 | c.1666del p.T556Lfs*17 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2
- RBM12 | c.1824del p.K608Nfs*11 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- RFX6 | c.872del p.L291Yfs*53 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- RGL3 | c.1253del p.P418Qfs*57 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- RPRD2 | c.788del p.N263Tfs*5 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | called by mutect2, pindel, varscan2
- RSBN1L | c.1646del p.N549Ifs*27 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- RUBCNL | c.1970_1971del p.V657Gfs*21 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- SELENON | c.446del p.P149Lfs*? | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- SEZ6L2 | c.1229del p.G410Afs*7 (on ENST00000308713 / NM_001114099.3; = p.G340Afs*7 on NM_012410.4) | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- SIPA1 | c.2359del p.A787Pfs*12 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.4713del p.S1572Afs*57 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- SLC12A1 | c.2205del p.K735Nfs*6 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.169del p.I57* | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- SLC6A14 | c.1878dup p.E627Rfs*3 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | called by mutect2, pindel, varscan2
- SOAT1 | c.195del p.F65Lfs*2 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- SOCS6 | c.1400del p.N467Mfs*21 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- SPRR3 | c.494_496del p.K165del | In Frame Del (DEL) | VAF 7/27 reads (26%) | called by pindel, varscan2
- ST8SIA3 | c.104del p.K35Rfs*31 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- STAB1 | c.2398del p.V800Cfs*113 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- TK1 | c.508_510del p.K170del | In Frame Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel, varscan2
- TNF | c.69del p.Q25Rfs*15 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.98249del p.P32750Hfs*4 (on ENST00000591111; = p.P25326Hfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- TXK | c.620del p.K207Rfs*21 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- UBA5 | c.297+7del | Splice Region (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- UBE2K | c.496dup p.I166Nfs*10 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- VASP | c.231del p.N78Tfs*33 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- ZBTB1 | c.1571del p.K524Sfs*25 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- ZDHHC8 | c.1049del p.P350Rfs*33 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- ZEB1 | c.1576del p.V526* | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- ZKSCAN7 | c.579del p.S194Vfs*45 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- ZNF561 | c.293dup p.L98Ffs*22 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- ABCA5 | c.717T>C p.H239= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101201192; called by muse, mutect2
- ABRA | c.177A>G p.S59= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100357619; called by muse, mutect2, varscan2
- ACSM3 | c.1527C>T p.V509= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99184719; called by muse, mutect2, varscan2
- ADAM29 | c.981A>G p.S327= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100822107; called by muse, mutect2, varscan2
- ADAMTS18 | c.1017C>T p.N339= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs373600403; called by muse, mutect2, varscan2
- ADAMTSL2 | c.708G>A p.P236= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs146958778; called by muse, mutect2, varscan2
- ADH4 | c.42C>T p.I14= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs143067434, COSV55503014; called by muse, mutect2, varscan2
- AL136295.1 | c.543C>T p.G181= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs375497293; called by muse, mutect2, varscan2
- ALKBH2 | c.651G>A p.P217= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs770725122, COSV57449970; called by muse, mutect2, varscan2
- ALPK2 | c.4218T>C p.I1406= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100864542; called by muse, mutect2, varscan2
- ARHGAP20 | c.1104A>G p.P368= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99504609; called by muse, mutect2, varscan2
- ARHGAP29 | c.3180C>T p.D1060= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs780050775, COSV53115996; called by muse, mutect2, varscan2
- ARL14 | c.477C>T p.L159= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV57900309; called by mutect2, varscan2
- ART5 | c.594C>A p.T198= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs781119812, COSV100731674; called by muse, mutect2, varscan2
- ASPA | c.780C>T p.P260= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV99559267; called by muse, mutect2, varscan2
- BAIAP2 | c.1407C>T p.P469= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs200377602, COSV100348462, COSV58334269; called by muse, varscan2
- BCKDK | c.1071C>T p.G357= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs531591891, COSV99570734; called by muse, mutect2, varscan2
- BICC1 | c.1905C>A p.S635= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99570717; called by muse, mutect2, varscan2
- BRDT | c.2523G>A p.R841= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV62863000; called by muse, mutect2, varscan2
- BUB1 | c.1821G>A p.A607= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs772143908, COSV100241428; called by muse, mutect2, varscan2
- C17orf98 | c.426G>A p.T142= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs1332277976; called by muse, mutect2, varscan2
- CALY | c.39T>C p.G13= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99428664; called by muse, mutect2, varscan2
- CAMSAP3 | c.327G>A p.A109= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs761428063, COSV99351288; called by muse, mutect2, varscan2
- CASK | c.45C>T p.C15= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs776956039, COSV100587418; called by muse, mutect2, varscan2
- CASZ1 | c.3807G>A p.A1269= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs373248558, COSV59742470; called by muse, mutect2
- CBFA2T3 | c.1122G>A p.V374= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99242094; called by muse, mutect2, varscan2
- CCDC17 | c.768C>T p.D256= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99322534; called by muse, mutect2, varscan2
- CCDC89 | c.1065C>T p.S355= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100320886; called by muse, mutect2, varscan2
- CDCA2 | c.30T>C p.P10= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99648698; called by muse, mutect2, varscan2
- CDH8 | c.462T>C p.I154= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100182966; called by muse, mutect2, varscan2
- CELSR1 | c.5103C>A p.S1701= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV53088014; called by muse, mutect2
- CENPJ | c.777G>A p.A259= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs748696673, COSV101121539; called by muse, varscan2
- CEP164 | c.3990G>A p.T1330= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs759899672, COSV99633785; called by muse, mutect2, varscan2
- CGB5 | c.193C>T p.L65= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- CHD4 | c.1080C>T p.C360= (on ENST00000357008 / NM_001363606.2; = p.C373= on NM_001273.5) | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs779177743, COSV58906602; called by muse, mutect2, varscan2
- CLEC12B | c.480T>C p.N160= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV100139046; called by muse, mutect2, varscan2
- CLPP | c.441C>T p.C147= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs752826199, COSV55536103; called by muse, mutect2, varscan2
- CNKSR3 | c.1491G>A p.A497= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV101401376; called by muse, mutect2, varscan2
171 further variants in this file (0 protein-altering or splice-affecting, 148 silent, 23 other) are not listed here.
